Gene-level copy-number profile of tumor specimen TCGA-PG-A915-01A from TCGA case TCGA-PG-A915, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,119 days).
Specimen TCGA-PG-A915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.fa9a5214-e8f8-4803-9f7e-440e7cd32820.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PG-A915-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/697c55ea-e091-41e7-8f07-022fe394493b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 129; copy number 2: 9,779; copy number 3: 23,540; copy number 4: 18,818; copy number 5: 4,547; copy number 6: 1,170; copy number 7: 542; copy number 8: 445; copy number 9: 149; copy number 10: 368; copy number 12: 46; copy number 13: 45; copy number 14: 19; copy number 15: 15; copy number 16: 28; copy number 17: 12; copy number 18: 21; copy number 20: 73; copy number 26: 58; copy number 29: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PG-A915-01A-11D-A37M-01): tumor purity 0.85, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,829 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:82,212,413–84,556,688, 24 genes, copy number 10–13 (within-gene range 3–13): AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712, LINC01725, AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3.
- chr1:115,029,826–117,321,336, 56 genes, copy number 7 (within-gene range 5–7): TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1, LINC02868, GAPDHP64, NEFHP1, CD2, FTH1P22, AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525.
- chr1:143,343,180–147,517,875, 139 genes, copy number 7 (broad region; genes not listed).
- chr1:149,887,890–150,629,612, 35 genes, copy number 9 (within-gene range 5–9): BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr1:151,176,304–152,196,699, 59 genes, copy number 9 (within-gene range 3–9): VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr5:54,808,210–54,957,846, 4 genes, copy number 8 (within-gene range 6–8): CSPG4BP, AC112198.1, AC112198.3, AC112198.2.
- chr5:95,964,999–96,215,519, 6 genes, copy number 10: AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1.
- chr5:96,814,028–98,929,007, 38 genes, copy number 14–20 (within-gene range 6–20): AC009126.1, ERAP2, LNPEP, AC008850.1, Y_RNA, SETP22, LIX1-AS1, LIX1, RIOK2, RNU1-73P, AC008883.3, AC008883.1, AC008883.2, AC074133.1, YTHDF1P1, AC106748.1, LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P.
- chr5:98,936,638–98,954,972, 2 genes, copy number 20: Y_RNA, AC022121.1.
- chr5:103,880,129–105,923,108, 11 genes, copy number 9–18: AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189.
- chr6:49,273,600–49,580,166, 8 genes, copy number 29: FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P.
- chr6:50,411,844–50,898,225, 7 genes, copy number 12: AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1.
- chr6:55,434,373–56,433,213, 8 genes, copy number 10: HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7.
- chr8:150,584–1,801,711, 34 genes, copy number 8 (within-gene range 6–8): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:100,337,595–100,350,707, 1 gene, copy number 7: AP001574.1.
- chr8:100,382,763–100,382,845, 1 gene, copy number 7: MIR4471.
- chr10:75,279,726–75,401,246, 1 gene, copy number 7 (within-gene range 5–7): AC010997.3.
- chr10:75,382,393–75,431,588, 6 genes, copy number 7: SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,552,553, 2 genes, copy number 7: AC010997.6, MIR606.
- chr11:125,955,796–126,440,344, 21 genes, copy number 12 (within-gene range 3–12): CDON, NAP1L1P1, AP000821.1, AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3.
- chr13:76,552,807–88,630,397, 120 genes, copy number 7–16 (broad region; genes not listed).
- chr13:97,221,434–99,432,702, 47 genes, copy number 7 (within-gene range 6–7): MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, AL136961.1.
- chr13:104,125,930–113,490,951, 134 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr16:30,378,106–32,003,728, 137 genes, copy number 8 (broad region; genes not listed).
- chr19:10,221,433–24,004,507, 747 genes, copy number 7–26 (broad region; genes not listed).
- chr19:29,083,094–30,713,538, 30 genes, copy number 12–17 (within-gene range 1–17): AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536.
- chr19:39,083,913–39,834,201, 52 genes, copy number 20: ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719.
- chr19:45,863,989–46,031,667, 9 genes, copy number 26: FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3.
- chr20:34,194,569–34,540,958, 17 genes, copy number 7 (within-gene range 4–7): ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA.
- chr22:29,268,009–30,674,134, 70 genes, copy number 13–26 (within-gene range 3–26) (broad region; genes not listed).
- chr22:30,731,557–30,731,641, 1 gene, copy number 13: MIR3200.
- chr22:34,017,422–34,218,796, 2 genes, copy number 9 (within-gene range 5–9): LINC01643, Z68323.1.

Autosomal genes at a single copy (total copy number 1): 129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
